Gene-level copy-number profile of tumor specimen ALCH-B4EV-TTP1-A from ALCHEMIST case ALCH-B4EV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.5 years (22,104 days).
Specimen ALCH-B4EV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ea824088-159c-42d6-98aa-029a410cd7cd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4EV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,257 have no estimate.
https://portal.gdc.cancer.gov/files/ec3859e5-8a2a-4c5c-8d9f-0b5d7221371d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 9,352; copy number 2: 37,483; copy number 3: 6,611; copy number 4: 4,701; copy number 5: 178; copy number 6: 13; copy number 17: 2; copy number 37: 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:48,620,759–48,672,733, 7 genes: TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793, LINC02585, AC141002.1.
- chr5:1,005,039–1,006,623, 1 gene: AC116351.2.
- chr6:32,005,636–32,035,418, 4 genes (within-gene range 0–5): CYP21A1P, TNXA, STK19B, C4B.
- chr6:32,038,327–32,041,644, 1 gene (within-gene range 0–2): CYP21A2.
- chr9:125,372,325–125,417,586, 2 genes: AL627223.1, Metazoa_SRP.
- chr11:46,701,030–46,705,912, 1 gene: ZNF408.
- chr11:66,312,853–66,319,237, 2 genes: AP001107.3, CD248.
- chr13:45,060,729–45,061,086, 1 gene (within-gene range 0–1): RN7SKP3.
- chr14:100,675,930–100,679,884, 1 gene (within-gene range 0–3): AL132711.1.
- chr19:647,526–663,233, 1 gene: RNF126.
- chr19:49,361,783–49,388,091, 2 genes (within-gene range 0–2): DKKL1, AC010643.1.
- chr19:50,466,785–50,476,848, 1 gene (within-gene range 0–5): FAM71E1.
- chr21:44,133,610–44,210,114, 1 gene (within-gene range 0–6): GATD3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 194 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,748,087–87,825,952, 2 genes, copy number 17 (within-gene range 4–17): PLGLB2, RGPD2.
- chr6:32,032,713–32,036,258, 1 gene, copy number 5 (within-gene range 0–5): C4B-AS1.
- chr11:2,268,495–2,270,952, 1 gene, copy number 5: ASCL2.
- chr11:66,257,294–66,296,664, 10 genes, copy number 5: KLC2, AP001107.4, AP001107.8, AP001107.7, RAB1B, AP001107.1, AP001107.2, CNIH2, YIF1A, TMEM151A.
- chr14:18,555,677–18,596,310, 4 genes, copy number 5: CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr14:22,197,446–22,482,959, 1 gene, copy number 5 (within-gene range 3–5): AC244502.1.
- chr14:22,314,490–22,540,306, 70 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr14:100,879,753–100,903,722, 1 gene, copy number 5 (within-gene range 3–5): RTL1.
- chr14:100,894,817–100,927,413, 6 genes, copy number 5: AL117190.6, SNORD112, AL117190.4, MIR370, SNORD113-1, SNORD113-2.
- chr16:1,972,053–2,047,866, 11 genes, copy number 6 (within-gene range 2–6): TBL3, NOXO1, GFER, AC005606.2, SYNGR3, AC005606.1, ZNF598, NPW, RN7SL219P, SLC9A3R2, NTHL1.
- chr16:29,425,800–30,123,506, 62 genes, copy number 5 (broad region; genes not listed).
- chr16:30,524,004–30,627,178, 16 genes, copy number 5: ZNF768, AC002310.4, AC002310.5, ZNF747, AC002310.1, AC002310.3, ZNF764, ZNF688, AC002310.2, ZNF785, AC093249.2, AC093249.4, ZNF689, AC093249.3, AC093249.5, AC093249.1.
- chr19:50,476,400–50,490,871, 3 genes, copy number 5 (within-gene range 0–5): EMC10, AC020909.3, AC020909.2.
- chr21:8,603,547–8,603,984, 1 gene, copy number 6: RPSAP68.
- chr21:43,092,956–43,107,570, 1 gene, copy number 5: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 5–37: MRPL51P2, FRGCA.
- chr21:44,158,740–44,160,076, 1 gene, copy number 6: LINC01678.

Autosomal genes at a single copy (total copy number 1): 9,352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
